Somatic mutation profile of tumor specimen TCGA-QD-A8IV-01A (aliquot TCGA-QD-A8IV-01A-11D-A397-08) from TCGA case TCGA-QD-A8IV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 50.1 years (18,288 days).
Specimen TCGA-QD-A8IV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b42a35bc-0578-4b7a-a46c-e4846b0cd3fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QD-A8IV-10A (Blood Derived Normal), aliquot TCGA-QD-A8IV-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a61d9c17-514b-4c73-82ff-c792cfe607fe

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 72/160 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COG3 | c.1133A>T p.Q378L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100596518; called by muse, mutect2, varscan2
- CYLD | c.2655G>A p.W885* | Nonsense Mutation (SNP) | VAF 72/190 reads (38%) | catalogued as CM111033, COSV100282439; called by muse, mutect2, varscan2
- MRPL28 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as COSV99170669; called by muse, mutect2, varscan2
- NDUFV2 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771897446, COSV100571717; called by muse, mutect2, varscan2
- POU2F3 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 121/293 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.099); catalogued as COSV99501121; called by muse, mutect2, varscan2
- ACTL9 | c.993C>T p.R331= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV61007160; called by muse, mutect2, varscan2
- ARHGEF17 | c.4359C>T p.F1453= | Silent (SNP) | VAF 67/155 reads (43%) | catalogued as COSV55232179; called by muse, mutect2, varscan2
- CNTN5 | c.1851G>A p.E617= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99676928; called by muse, mutect2, varscan2
- GABRE | c.258G>T p.L86= | Silent (SNP) | VAF 47/134 reads (35%) | catalogued as COSV100944274; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1137C>T p.N379= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs777231345, COSV100781288; called by muse, mutect2, varscan2
